Somatic mutation profile of tumor specimen TCGA-CG-4438-01A (aliquot TCGA-CG-4438-01A-01D-1158-08) from TCGA case TCGA-CG-4438, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 56.3 years (20,574 days).
Specimen TCGA-CG-4438-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 71565c8a-5071-4fd8-8e08-0cf6fa131aa3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-4438-10A (Blood Derived Normal), aliquot TCGA-CG-4438-10A-01D-1158-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26175409-6911-4ea3-b637-73e3afedd56f

The open-access MAF lists 146 somatic variants for this specimen: 115 protein-altering or splice-affecting, 28 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 103, Silent 28, Nonsense Mutation 6, Intron 3, Splice Region 2, Splice Site 1, In Frame Del 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 23/37 reads (62%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AAAS | c.683C>G p.S228C | Missense Mutation (SNP) | VAF 53/283 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV52933028; called by muse, mutect2, varscan2
- ADAMTS16 | c.1724T>G p.V575G | Missense Mutation (SNP) | VAF 74/155 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV56990857; called by muse, mutect2, varscan2
- ADGRA1 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776693044, COSV66924677; called by muse, mutect2, varscan2
- AK7 | c.1172A>G p.Y391C | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1338243436, COSV50872096; called by muse, mutect2, varscan2
- AKAP13 | c.6508G>C p.E2170Q (on ENST00000394518 / NM_007200.5; = p.E2174Q on NM_006738.6) | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764296768, COSV63456661, COSV63457901; called by muse, mutect2, varscan2
- AKNAD1 | c.2233G>A p.E745K | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV62198752; called by muse, mutect2, varscan2
- ANKRD11 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 86/149 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56361477; called by muse, mutect2, varscan2
- ASAP3 | c.1466C>G p.S489C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60874860; called by muse, mutect2, varscan2
- ATP7A | c.180G>C p.K60N | Missense Mutation (SNP) | VAF 60/313 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV58446661; called by muse, mutect2, varscan2
- BEGAIN | c.38A>C p.E13A | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV62068815; called by muse, mutect2, varscan2
- BMP6 | c.1086C>A p.F362L | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51665823; called by muse, mutect2, varscan2
- C18orf54 | c.506A>G p.H169R | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs956257985, COSV55618135; called by muse, mutect2, varscan2
- CASD1 | c.1996G>C p.E666Q | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV51972645; called by muse, mutect2, varscan2
- CCDC144A | c.1990A>C p.K664Q | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.105); catalogued as COSV100138271; called by muse, mutect2, varscan2
- CCSER2 | c.1651G>T p.D551Y | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56505688; called by muse, mutect2, varscan2
- CFAP74 | c.1602G>C p.K534N | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV54568100; called by muse, mutect2, varscan2
- CKAP4 | c.688T>G p.F230V | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65172614; called by muse, mutect2, varscan2
- COL11A1 | c.1918G>T p.G640* | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as COSV62184270; called by muse, mutect2, varscan2
- COL19A1 | c.952C>A p.H318N | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.043); catalogued as COSV59573996; called by muse, mutect2, varscan2
- CSF3 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as rs767498933, COSV56639974; called by muse, mutect2, varscan2
- DACH2 | c.1546C>T p.Q516* | Nonsense Mutation (SNP) | VAF 21/28 reads (75%) | catalogued as COSV64169462, COSV64184965; called by muse, mutect2, varscan2
- DDHD1 | c.1915G>T p.V639F (on ENST00000323669; = p.V836F on NM_030637.3) | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.135); catalogued as COSV60359567; called by muse, mutect2, varscan2
- DGKI | c.2906C>T p.T969I | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.214); catalogued as COSV55951451; called by muse, mutect2
- DIP2A | c.3535A>G p.I1179V | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs758779594, COSV59477958; called by muse, mutect2, varscan2
- DYNC2I2 | c.1436C>T p.T479I | Missense Mutation (SNP) | VAF 62/113 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.229); catalogued as rs749760692, COSV63987288; called by muse, mutect2, varscan2
- EPHA7 | c.1805T>A p.F602Y | Missense Mutation (SNP) | VAF 85/238 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.087); catalogued as COSV65183190; called by muse, mutect2, varscan2
- FAT4 | c.8188G>A p.V2730I | Missense Mutation (SNP) | VAF 94/126 reads (75%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs369228145; called by muse, mutect2, varscan2
- FBXO31 | c.554C>G p.P185R | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs1342589854, COSV61149043; called by muse, mutect2, varscan2
- FMO3 | c.1550T>G p.L517R | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as COSV63007324; called by muse, mutect2, varscan2
- GABBR1 | c.344C>T p.T115M | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.286); catalogued as rs757008467, COSV63540730; called by muse, mutect2, varscan2
- GEN1 | c.775G>C p.A259P | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV58056669; called by muse, mutect2, varscan2
- GSDMA | c.1006G>A p.V336I | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs769786576, COSV56976798; called by muse, mutect2, varscan2
- HECW1 | c.3799G>C p.V1267L | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV67830083, COSV67838791; called by muse, mutect2, varscan2
- HEXB | c.658C>T p.L220F | Missense Mutation (SNP) | VAF 39/61 reads (64%) | SIFT tolerated (0.1); PolyPhen benign (0.359); catalogued as COSV54667865; called by muse, mutect2, varscan2
- HEXIM1 | c.856G>C p.E286Q | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.9); catalogued as COSV100203493, COSV60177094; called by muse, mutect2, varscan2
- HIPK4 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs757043623, COSV52521251; called by muse, mutect2, varscan2
- HLA-A | c.971G>C p.G324A | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.997); catalogued as rs746131702, COSV65140773; called by muse, mutect2
- HLA-DMB | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs12176347, COSV66870773; called by muse, mutect2, varscan2
- HMCN1 | c.6762A>C p.L2254F | Missense Mutation (SNP) | VAF 54/97 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54902285; called by muse, mutect2, varscan2
- IPCEF1 | c.764A>G p.H255R | Missense Mutation (SNP) | VAF 114/347 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV54544695; called by muse, mutect2, varscan2
- IRAG2 | c.3108A>G p.Q1036= (on ENST00000636465; = p.Q81= on NM_006152.4 and 7 other RefSeq transcripts) | Splice Region (SNP) | VAF 33/72 reads (46%) | catalogued as rs764230629, COSV63138902; called by muse, mutect2, varscan2
- KCNA3 | c.704G>A p.G235D | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as COSV63901650; called by muse, mutect2, varscan2
- KCNQ2 | c.1705G>A p.E569K (on ENST00000359125 / NM_172107.4; = p.E541K on NM_004518.6) | Missense Mutation (SNP) | VAF 91/359 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60545594; called by muse, mutect2, varscan2
- KHDC4 | c.424A>G p.R142G | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV64165048; called by muse, mutect2
- KIF2B | c.1915G>A p.A639T | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.061); catalogued as COSV52129345, COSV52130855; called by muse, mutect2, varscan2
- KLHL1 | c.488G>T p.C163F | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV64772910; called by muse, mutect2, varscan2
- KMT2A | c.11146G>A p.G3716S | Missense Mutation (SNP) | VAF 68/268 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1206696338, COSV63286041; called by muse, mutect2, varscan2
- KMT2D | c.9245G>A p.R3082Q | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as rs1467406954, COSV56442104; called by muse, mutect2, varscan2
- MDN1 | c.6858C>T p.F2286= | Splice Region (SNP) | VAF 27/197 reads (14%) | catalogued as COSV65522063; called by muse, mutect2, varscan2
- MED12 | c.2047G>C p.D683H | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV61340663, COSV61355500; called by muse, mutect2, varscan2
- MEFV | c.1659A>G p.I553M | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs769163866, COSV54822338; called by muse, mutect2, varscan2
- MICU3 | c.1411T>C p.S471P | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV58846244; called by muse, mutect2, varscan2
- MTERF4 | c.823C>A p.Q275K | Missense Mutation (SNP) | VAF 137/255 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV54089131; called by muse, mutect2, varscan2
- NALCN | c.4820G>A p.R1607Q | Missense Mutation (SNP) | VAF 75/106 reads (71%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs370886839, COSV99218045; called by muse, mutect2, varscan2
- NOSTRIN | c.1456C>T p.H486Y (on ENST00000317647 / NM_001039724.4; = p.H408Y on NM_052946.3) | Missense Mutation (SNP) | VAF 64/123 reads (52%) | SIFT tolerated (0.57); PolyPhen benign (0.022); catalogued as COSV58321591; called by muse, mutect2, varscan2
- NRAP | c.2923G>A p.D975N (on ENST00000359988 / NM_001322945.2; = p.D940N on NM_006175.4) | Missense Mutation (SNP) | VAF 63/251 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.654); catalogued as COSV63490818; called by muse, mutect2, varscan2
- NUTM1 | c.2851G>A p.E951K | Missense Mutation (SNP) | VAF 41/55 reads (75%) | SIFT deleterious (0.05); PolyPhen benign (0.107); catalogued as COSV59216978; called by muse, mutect2, varscan2
- OGFR | c.382C>T p.H128Y | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51699086; called by muse, mutect2
- OR2T6 | c.118A>G p.I40V | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV63216365; called by muse, mutect2, varscan2
- OTP | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 70/116 reads (60%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.811); catalogued as rs867548437, COSV60568883; called by muse, mutect2, varscan2
- PBRM1 | c.2999G>A p.R1000Q | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750583919, COSV56277699, COSV56306314; called by muse, mutect2, varscan2
- PBX3 | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.899); catalogued as rs778017986, COSV100655185, COSV60732355; called by muse, mutect2, varscan2
- PCDHGA7 | c.2152C>T p.R718C | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.081); catalogued as rs1222079447, COSV99529042; called by muse, mutect2, varscan2
- PDLIM1 | c.533+1G>A p.X178_splice | Splice Site (SNP) | VAF 20/51 reads (39%) | catalogued as rs778264797, COSV61473419; called by muse, varscan2
- PDYN | c.53C>T p.T18I | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1555778420, COSV54101877, COSV54103082; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PEG3 | c.4726C>T p.R1576C | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as rs752608830, COSV55632721; called by muse, mutect2, varscan2
- PIH1D2 | c.203T>G p.I68S | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54775521; called by muse, mutect2, varscan2
- PIK3C2B | c.1495A>C p.I499L | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.076); catalogued as COSV65803663; called by muse, mutect2, varscan2
- PKD1L1 | c.1282G>C p.V428L | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV56965816; called by muse, mutect2, varscan2
- PKHD1 | c.8749A>G p.K2917E | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as COSV61876814; called by muse, mutect2, varscan2
- PKHD1L1 | c.8537G>A p.R2846H | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs375835470; called by muse, mutect2, varscan2
- PLB1 | c.2141G>T p.W714L | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.77); PolyPhen benign (0.108); catalogued as COSV59825920, COSV59835385; called by muse, mutect2, varscan2
- PLG | c.2322A>C p.L774F | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV57516422; called by muse, mutect2
- PPARA | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as COSV99415036; called by muse, mutect2, varscan2
- PRDX4 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 63/150 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.157); catalogued as COSV65018684; called by muse, mutect2, varscan2
- PROSER1 | c.965C>G p.S322* | Nonsense Mutation (SNP) | VAF 10/68 reads (15%) | catalogued as COSV61487530; called by muse, mutect2, varscan2
- PRR19 | c.487C>G p.R163G | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.049); catalogued as COSV56625418; called by muse, mutect2, varscan2
- PSG1 | c.389G>C p.G130A | Missense Mutation (SNP) | VAF 84/576 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0.023); catalogued as COSV54949713; called by muse, mutect2, varscan2
- PUM1 | c.2975C>T p.A992V | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV57085701; called by muse, mutect2, varscan2
- RAB11FIP2 | c.97A>G p.T33A | Missense Mutation (SNP) | VAF 127/294 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV62925263; called by muse, mutect2, varscan2
- RAB30 | c.356T>C p.L119S | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52626760; called by muse, mutect2, varscan2
- RAB4B | c.332G>T p.S111I | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV63824500; called by muse, mutect2, varscan2
- RBM39 | c.1217A>G p.Q406R (on ENST00000253363 / NM_001323424.2; = p.Q400R on NM_004902.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/227 reads (6%) | SIFT tolerated (0.63); PolyPhen benign (0.157); catalogued as COSV53615447; called by muse, mutect2
- RELCH | c.1949A>C p.E650A | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV56885903; called by muse, mutect2, varscan2
- RNF207 | c.848T>G p.L283W | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65007674; called by muse, mutect2, varscan2
- RYR1 | c.10883G>T p.R3628L | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62097143, COSV62098162; called by muse, mutect2
- SDE2 | c.1099G>A p.V367I | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs377596622, COSV55253968; called by muse, mutect2
- SIRPB1 | c.1186C>T p.Q396* | Nonsense Mutation (SNP) | VAF 7/41 reads (17%) | catalogued as COSV53538883, COSV53539691; called by muse, mutect2, varscan2
- SLC26A3 | c.65A>T p.E22V | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.045); catalogued as COSV60640423; called by muse, mutect2, varscan2
- SLC48A1 | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as rs747390223, COSV50358517; called by muse, mutect2, varscan2
- SP140 | c.314C>T p.T105I | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as rs746076516, COSV59450152; called by muse, mutect2, varscan2
- SYNE1 | c.3730T>A p.S1244T (on ENST00000367255 / NM_182961.4; = p.S1251T on NM_033071.3) | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV54912534, COSV54988654; called by muse, mutect2, varscan2
- SYNE1 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 44/293 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs375917264; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAF5 | c.1672C>A p.L558M | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.273); catalogued as COSV58915740; called by muse, mutect2, varscan2
- TBX5 | c.980A>C p.K327T | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.371); catalogued as COSV59861483; called by muse, mutect2, varscan2
- TIAM2 | c.1561G>A p.V521M | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.108); catalogued as COSV59694714; called by muse, mutect2, varscan2
- TLL2 | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV63572599; called by muse, mutect2, varscan2
- TLR1 | c.1646G>A p.G549D | Missense Mutation (SNP) | VAF 95/369 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.049); catalogued as COSV58304348; called by muse, mutect2, varscan2
- TOPORS | c.3112C>G p.L1038V | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.163); catalogued as COSV62117003; called by muse, mutect2, varscan2
- TRAV39 | c.107A>T p.N36I | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.132); catalogued as rs748904689; called by muse, varscan2
- TRIM2 | c.880C>T p.R294W (on ENST00000437508; = p.R321W on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as COSV58633996; called by muse, mutect2, varscan2
- UBE2Q1 | c.355T>A p.W119R | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52725211; called by muse, mutect2, varscan2
- UCHL3 | c.170C>G p.P57R | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66459665; called by muse, mutect2, varscan2
- WSCD2 | c.409_410insT p.D137Vfs*14 | Frame Shift Ins (INS) | VAF 8/48 reads (17%) | catalogued as COSV99773945; called by mutect2, pindel, varscan2
- ZBTB14 | c.207G>T p.E69D | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.031); catalogued as COSV63696733; called by muse, mutect2, varscan2
- ZFP28 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV56735971; called by muse, mutect2, varscan2
- ZNF345 | c.1268A>G p.E423G | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV59324151; called by muse, mutect2, varscan2
- ZNF462 | c.3650G>C p.R1217P | Missense Mutation (SNP) | VAF 119/471 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); catalogued as COSV52938924, COSV52944625; called by muse, mutect2, varscan2
- ZNF569 | c.1177C>G p.Q393E | Missense Mutation (SNP) | VAF 39/188 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.084); catalogued as COSV57593809; called by muse, mutect2, varscan2
- FCGBP | c.5699G>C p.S1900T | Missense Mutation (SNP) | VAF 72/655 reads (11%) | SIFT tolerated (0.77); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- KCNA1 | c.812_827del p.T271Rfs*22 | Frame Shift Del (DEL) | VAF 24/182 reads (13%) | called by mutect2, pindel
- PITPNM1 | c.1412_1420del p.A471_H474delinsD | In Frame Del (DEL) | VAF 28/110 reads (25%) | called by mutect2, pindel, varscan2
- TBC1D3F | c.152T>C p.I51T | Missense Mutation (SNP) | VAF 72/146 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.234); called by mutect2, varscan2
- TRAV8-2 | c.13C>G p.L5V | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ADCY1 | c.2655C>T p.D885= | Silent (SNP) | VAF 34/143 reads (24%) | catalogued as rs756397815, COSV52035071; called by mutect2, varscan2
- APOL3 | c.774C>T p.T258= (on ENST00000349314 / NM_145640.2; = p.T187= on NM_014349.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as COSV62579845; called by muse, mutect2, varscan2
- ATAD5 | c.2577G>A p.V859= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV58974860; called by muse, mutect2, varscan2
- DNAH9 | c.8502G>C p.L2834= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV52338781, COSV52350932; called by muse, mutect2, varscan2
- DUSP10 | c.903C>T p.S301= | Silent (SNP) | VAF 65/129 reads (50%) | catalogued as rs756540076, COSV60457671; called by muse, mutect2, varscan2
- ELMOD1 | c.960G>A p.A320= | Silent (SNP) | VAF 75/250 reads (30%) | catalogued as rs764635964, COSV56192809; called by muse, mutect2, varscan2
- ERC2 | c.471G>T p.L157= | Silent (SNP) | VAF 62/272 reads (23%) | catalogued as COSV55606283; called by muse, varscan2
- KIAA1109 | c.5094G>A p.T1698= | Silent (SNP) | VAF 27/89 reads (30%) | catalogued as rs750412331, COSV52674432; called by muse, mutect2, varscan2
- LAMA2 | c.4419G>A p.L1473= | Silent (SNP) | VAF 84/205 reads (41%) | catalogued as COSV70347756; called by muse, mutect2, varscan2
- LRRC43 | c.1056C>T p.G352= | Silent (SNP) | VAF 25/130 reads (19%) | catalogued as rs779792928, COSV60290130, COSV60293387; called by muse, mutect2, varscan2
- LRRC47 | c.564C>T p.D188= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV65562543; called by muse, mutect2, varscan2
- LTBP3 | c.1965G>A p.G655= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs747104260, COSV57240720; called by muse, mutect2, varscan2
- MARK3 | c.204A>G p.A68= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as COSV53508394; called by muse, mutect2, varscan2
- MUC5B | c.15651C>G p.T5217= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV101499979, COSV71594421; called by muse, mutect2, varscan2
- NDST2 | c.2202A>G p.S734= | Silent (SNP) | VAF 15/227 reads (7%) | catalogued as COSV55214549; called by muse, mutect2
- OR52L1 | c.804C>T p.V268= | Silent (SNP) | VAF 42/102 reads (41%) | catalogued as COSV59987419; called by muse, mutect2, varscan2
- PLCB1 | c.2892C>T p.A964= | Silent (SNP) | VAF 12/119 reads (10%) | catalogued as rs546783466, COSV62052119; called by muse, mutect2, varscan2
- PPP1R3A | c.288G>A p.T96= | Silent (SNP) | VAF 36/134 reads (27%) | catalogued as rs111896635; called by muse, mutect2, varscan2
- PREX2 | c.4023A>C p.A1341= | Silent (SNP) | VAF 27/172 reads (16%) | catalogued as COSV55771695; called by muse, mutect2, varscan2
- SLC3A1 | c.1881C>T p.A627= | Silent (SNP) | VAF 74/122 reads (61%) | catalogued as rs763292534, COSV53216673; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- SLC6A5 | c.1677C>G p.L559= | Silent (SNP) | VAF 15/101 reads (15%) | catalogued as COSV54227026; called by muse, mutect2, varscan2
- TMEM59L | c.876G>A p.A292= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs945919702, COSV53242319; called by muse, mutect2, varscan2
- WDR72 | c.2397G>T p.L799= | Silent (SNP) | VAF 76/403 reads (19%) | catalogued as COSV64747279; called by muse, mutect2, varscan2
- XAGE2 | c.42A>G p.R14= | Silent (SNP) | VAF 84/232 reads (36%) | called by muse, mutect2, varscan2
- ZFP64 | c.1086G>A p.E362= | Silent (SNP) | VAF 100/263 reads (38%) | catalogued as rs919618763, COSV53799399; called by muse, mutect2, varscan2
- ZNF142 | c.2469C>G p.P823= (on ENST00000411696 / NM_001379660.1; = p.P623= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV68743832; called by muse, mutect2, varscan2
- ZNF473 | c.696T>G p.T232= | Silent (SNP) | VAF 78/202 reads (39%) | catalogued as COSV54523295; called by muse, mutect2, varscan2
- ZNF543 | c.1485G>A p.T495= | Silent (SNP) | VAF 22/123 reads (18%) | catalogued as rs199904541, COSV58627575; called by muse, mutect2, varscan2
- CARS1 | c.26-5725C>G | Intron (SNP) | VAF 23/58 reads (40%) | catalogued as COSV53463181; called by muse, mutect2, varscan2
- ITCH | c.1548-3697G>A | Intron (SNP) | VAF 10/117 reads (9%) | catalogued as COSV99391856; called by muse, mutect2
- MACF1 | c.15832-9682del | Intron (DEL) | VAF 18/52 reads (35%) | called by mutect2, pindel, varscan2
